Somatic mutation profile of tumor specimen TCGA-HT-7611-01A (aliquot TCGA-HT-7611-01A-11D-2395-08) from TCGA case TCGA-HT-7611, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 36.5 years (13,314 days).
Specimen TCGA-HT-7611-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2a3fb26-99c3-4d46-a1b3-f2860ab95e1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7611-10B (Blood Derived Normal), aliquot TCGA-HT-7611-10B-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f95c08d4-bb7d-4c74-b45b-a17d76da6c0b

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 25/80 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 50/72 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2
- TTN | c.84916C>T p.R28306* (on ENST00000591111; = p.R20882* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs727505224, COSV60399336; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABO | c.388A>G p.K130E | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV71743713; called by muse, mutect2, varscan2
- AGAP1 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as rs779286450, COSV58341007; called by muse, mutect2
- AOC1 | c.1798A>G p.M600V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs764738237, COSV62871394; called by muse, mutect2, varscan2
- CDC42BPG | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200332352, COSV61348159; called by muse, mutect2, varscan2
- CHD9 | c.7446T>A p.D2482E (on ENST00000398510 / NM_001382353.1; = p.D2466E on NM_025134.7) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV54617640; called by muse, mutect2, varscan2
- CHRM5 | c.1339A>G p.I447V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373677487; called by muse, mutect2, varscan2
- CYP4F8 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs774126836, COSV57855723; called by muse, mutect2, varscan2
- DLK1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.58); catalogued as rs1325910940, COSV100375127; called by muse, mutect2
- FCGBP | c.10405G>A p.V3469M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.607); catalogued as rs1440916484; called by muse, mutect2, varscan2
- HAPLN1 | c.1016A>T p.D339V | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV57152588; called by muse, mutect2
- IFI35 | c.781G>A p.G261R (on ENST00000415816 / NM_001330230.2; = p.G263R on NM_005533.5) | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749072575, COSV55897135; called by muse, mutect2, varscan2
- KIAA0319 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749156433, COSV65497069; called by muse, mutect2, varscan2
- KNL1 | c.2680G>A p.D894N (on ENST00000346991 / NM_170589.5; = p.D868N on NM_144508.5) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs765489557, COSV61161312; called by muse, mutect2
- LCE3C | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV61610367; called by muse, mutect2, varscan2
- OR1Q1 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs544593447, COSV52917629; called by muse, mutect2, varscan2
- RNF19B | c.1940G>A p.C647Y | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV52390435; called by muse, mutect2, varscan2
- STOML3 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV65512160; called by muse, varscan2
- TRPM6 | c.4496T>C p.L1499P | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.454); catalogued as rs1222478884, COSV62525077; called by muse, mutect2, varscan2
- ATRX | c.2143_2147del p.K715Afs*4 | Frame Shift Del (DEL) | VAF 31/147 reads (21%) | called by mutect2, pindel, varscan2
- FOXM1 | c.362_363del p.L121Pfs*9 | Frame Shift Del (DEL) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- EPHB6 | c.2787C>T p.G929= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs759395004, COSV63894064; called by muse, mutect2, varscan2
- GPRC5B | c.987C>G p.A329= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV56029066; called by muse, mutect2
- GPRC5B | c.342C>A p.I114= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV56029077; called by muse, mutect2, varscan2
- PLEKHG4B | c.1440A>G p.L480= (on ENST00000283426; = p.L836= on NM_052909.5) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV52056630; called by muse, mutect2, varscan2
- SNAPIN | c.390C>T p.P130= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1310150311, COSV62628306; called by muse, mutect2, varscan2
